Somatic mutation profile of tumor specimen TCGA-BR-A4IY-01A (aliquot TCGA-BR-A4IY-01A-11D-A25D-08) from TCGA case TCGA-BR-A4IY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.4 years (21,314 days).
Specimen TCGA-BR-A4IY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ae48131-a7e1-4a18-961d-42fd0503f5a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4IY-10A (Blood Derived Normal), aliquot TCGA-BR-A4IY-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b92fce0f-7637-49ac-a56f-5a7232c43c27

The open-access MAF lists 150 somatic variants for this specimen: 118 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 31, Nonsense Mutation 8, Frame Shift Del 5, In Frame Del 4, Splice Site 3, Frame Shift Ins 1, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AARS2 | c.1188+1G>C p.X396_splice | Splice Site (SNP) | VAF 53/343 reads (15%) | catalogued as COSV55114107; called by muse, mutect2, varscan2
- ACLY | c.2567del p.G856Afs*39 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as COSV61249645; called by mutect2, pindel
- ACTL6A | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as COSV66998822; called by muse, mutect2, varscan2
- ADAMTS7 | c.1214G>C p.C405S | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66306558; called by muse, mutect2, varscan2
- ADAMTS7 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66306562; called by muse, mutect2, varscan2
- ADH6 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389809991, COSV52955698; called by muse, mutect2, varscan2
- ARHGEF17 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV55231162; called by muse, mutect2, varscan2
- ASTN2 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.537); catalogued as rs144385545, COSV57754351; called by muse, mutect2, varscan2
- ATP10B | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs368049318; called by muse, mutect2, varscan2
- ATP2C1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs142366167; called by muse, mutect2, varscan2
- ATR | c.57C>T p.G19= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63385346; called by muse, mutect2, varscan2
- BICD1 | c.2699C>G p.S900C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55677145; called by muse, mutect2, varscan2
- BTBD11 | c.2717G>A p.R906Q (on ENST00000280758 / NM_001018072.2; = p.R443Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.644); catalogued as COSV55021145; called by muse, mutect2, varscan2
- C1GALT1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56179084; called by muse, mutect2, varscan2
- C3AR1 | c.1399C>A p.H467N | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50817892; called by muse, mutect2, varscan2
- C6orf118 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs200810534; called by muse, mutect2, varscan2
- CD109 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54647624; called by muse, mutect2, varscan2
- CDH11 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs373083222; called by muse, mutect2, varscan2
- CDH8 | c.2209A>T p.T737S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.011); catalogued as COSV54858406; called by muse, mutect2, varscan2
- CHD5 | c.2239C>A p.H747N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV52417614; called by muse, mutect2, varscan2
- CNGA4 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752239459, COSV66005231; called by muse, mutect2, varscan2
- COL14A1 | c.4762C>A p.P1588T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.72); catalogued as rs547704009, COSV52850874; called by muse, mutect2, varscan2
- COL2A1 | c.3968G>T p.C1323F | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61529288; called by muse, mutect2, varscan2
- CPNE8 | c.1640C>A p.S547* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100504610; called by muse, mutect2, varscan2
- CSMD1 | c.6489T>G p.F2163L (on ENST00000520002; = p.F2162L on NM_033225.6) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV59303268; called by muse, mutect2, varscan2
- DCTN1 | c.1461G>T p.E487D | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV62620088; called by muse, mutect2, varscan2
- DNAH7 | c.5567C>T p.S1856F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56758155; called by muse, mutect2, varscan2
- DOCK3 | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs777151434, COSV56512681; called by muse, mutect2, varscan2
- DRC1 | c.1843C>A p.P615T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55499786; called by muse, mutect2, varscan2
- DTNBP1 | c.731T>G p.M244R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV59038985; called by muse, mutect2, varscan2
- EPHA4 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV56029727; called by muse, mutect2, varscan2
- FAM166B | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV63428173; called by muse, mutect2, varscan2
- FAM71F2 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66352000; called by muse, mutect2, varscan2
- FOXRED2 | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV53399373; called by muse, mutect2, varscan2
- FYCO1 | c.1734C>G p.N578K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV56114974; called by muse, mutect2, varscan2
- GBA | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as rs1275724188, CM1310397, COSV59169317; called by muse, mutect2, varscan2
- GPCPD1 | c.69T>A p.C23* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV66830480; called by muse, mutect2, varscan2
- GPX6 | c.161T>C p.I54T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs374992726, COSV62657209; called by muse, mutect2, varscan2
- H2BC4 | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58415446; called by muse, mutect2, varscan2
- HMCN1 | c.13012A>T p.K4338* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV54889046; called by muse, mutect2
- HOXD4 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60459621, COSV60460364; called by muse, mutect2, varscan2
- HSD3B7 | c.356C>A p.T119N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV52680165; called by muse, mutect2, varscan2
- HSPA12A | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV100979753, COSV65021653; called by muse, mutect2, varscan2
- IDH2 | c.1124G>A p.W375* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | catalogued as COSV51562336; called by muse, mutect2, varscan2
- IRX3 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as COSV61668023; called by muse, mutect2
- KATNB1 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs782157682, COSV65549596; called by muse, mutect2
- KCNQ2 | c.1640G>A p.R547Q (on ENST00000359125 / NM_172107.4; = p.R519Q on NM_004518.6) | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.851); catalogued as rs760984494, COSV60542565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD3 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV52065408; called by muse, mutect2
- KIAA1109 | c.2894G>T p.G965V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99165997; called by muse, mutect2
- KIF22 | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as COSV50714419; called by muse, mutect2, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- KRT25 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV56444300; called by muse, mutect2, varscan2
- LCP1 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59940256; called by muse, mutect2, varscan2
- MADD | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV60622218; called by muse, mutect2, varscan2
- MARCKSL1 | c.501_503del p.E168del | In Frame Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs781178665; called by pindel, varscan2
- MMP16 | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs200606225, COSV54158200; called by muse, mutect2, varscan2
- MUC17 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60284299; called by muse, mutect2, varscan2
- MYBBP1A | c.940C>G p.P314A | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54595978; called by muse, mutect2, varscan2
- MYO18B | c.6532C>T p.R2178W | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs371274815; called by mutect2, varscan2
- NINL | c.4008G>C p.E1336D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV54000525; called by muse, mutect2, varscan2
- NOX3 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143056669, COSV50149242; called by muse, mutect2, varscan2
- NRXN1 | c.1327T>A p.Y443N | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100455611; called by muse, mutect2, varscan2
- OR5T1 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1258560409, COSV57302212; called by muse, mutect2
- OVCH2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs920172894, COSV71952759; called by muse, mutect2, varscan2
- P2RY2 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | catalogued as COSV60775762; called by muse, mutect2, varscan2
- PACSIN1 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs765933304, COSV55059325; called by muse, mutect2, varscan2
- PAG1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773607722, COSV55056666; called by muse, mutect2, varscan2
- PAPPA2 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV62775756; called by muse, mutect2
- PCDHB11 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.045); catalogued as rs782776198, COSV61314859; called by mutect2, varscan2
- PDE2A | c.1022A>T p.D341V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV57804500; called by muse, mutect2, varscan2
- PDS5A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV57824219; called by muse, mutect2, varscan2
- PLXNA4 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs199571283, COSV58102572; called by muse, mutect2, varscan2
- POU4F2 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.122); catalogued as COSV55583614; called by muse, mutect2
- PPRC1 | c.3626A>G p.Q1209R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs756230353, COSV53384262; called by muse, mutect2, varscan2
- PRDM14 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1210022082, COSV52571462; called by muse, mutect2, varscan2
- PRUNE2 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV65039869; called by muse, mutect2, varscan2
- PTAFR | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV59536404; called by muse, mutect2, varscan2
- PTPRN2 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1335299565, COSV101234657, COSV99065342; called by muse, mutect2, varscan2
- PTPRN2 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101234659; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3200C>G p.S1067C | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62783048, COSV62785784; called by muse, mutect2, varscan2
- RBM14 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100036866, COSV59558447; called by muse, mutect2, varscan2
- RO60 | c.406A>C p.K136Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs761405121, COSV66473510; called by muse, mutect2, varscan2
- RORC | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs750446790, COSV59092251; called by muse, mutect2, varscan2
- RPUSD3 | c.422T>A p.L141H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67578869; called by muse, mutect2
- RXYLT1 | c.1313T>G p.L438* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV54168020; called by muse, mutect2
- SCAF1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as rs1319000028, COSV62182828; called by muse, mutect2, varscan2
- SEMA7A | c.801+1G>A p.X267_splice | Splice Site (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99984860; called by muse, mutect2
- SHOC1 | c.2806T>C p.S936P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV59499355; called by muse, mutect2, varscan2
- SNX29 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV60055518; called by muse, mutect2, varscan2
- SRMS | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV53916329; called by muse, mutect2, varscan2
- SV2C | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139844012, COSV59214450; called by muse, mutect2, varscan2
- TCN2 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53191008; called by muse, mutect2
- TIGD4 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV58549311; called by muse, mutect2, varscan2
- TOMM34 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV65688987; called by muse, mutect2, varscan2
- TSR3 | c.491G>C p.C164S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50103815; called by muse, mutect2, varscan2
- TSSK6 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as COSV53063037; called by muse, mutect2, varscan2
- TTN | c.62609A>G p.K20870R (on ENST00000591111; = p.K13446R on NM_003319.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | PolyPhen benign (0.001); catalogued as rs368046394; called by muse, mutect2, varscan2
- TUBA8 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV57812686; called by muse, mutect2, varscan2
- UGT2B11 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201490184, COSV71423198; called by muse, mutect2, varscan2
- USP12 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV56655457; called by muse, mutect2, varscan2
- VPS13A | c.2089A>C p.N697H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as COSV62427258; called by muse, mutect2, varscan2
- WDR62 | c.2075G>A p.C692Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54333389; called by muse, mutect2, varscan2
- YTHDF1 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as COSV64832703; called by muse, mutect2, varscan2
- Z83844.2 | c.520C>G p.H174D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60927784; called by muse, mutect2, varscan2
- ZMYND11 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59077387; called by muse, mutect2, varscan2
- ZNF440 | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58370670; called by muse, mutect2, varscan2
- ACACB | c.6192_6206del p.F2065_G2069del | In Frame Del (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel
- ADAMTS16 | c.803_822del p.P268Lfs*4 | Frame Shift Del (DEL) | VAF 18/196 reads (9%) | called by mutect2, pindel
- CEP57L1 | c.967_970del p.S324Nfs*3 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | called by mutect2, pindel, varscan2
- DST | c.9142_9144del p.E3048del | In Frame Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ECH1 | c.660-2_677del p.X220_splice | Splice Site (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- FOXN1 | c.878_891del p.P293Lfs*183 | Frame Shift Del (DEL) | VAF 8/85 reads (9%) | called by mutect2, pindel
- HNF1B | c.643G>C p.G215R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- IGKV1D-43 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- PSKH2 | c.652del p.T218Qfs*2 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- RECQL4 | c.985_990del p.R329_A330del | In Frame Del (DEL) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- SNX17 | c.182dup p.K63Efs*9 | Frame Shift Ins (INS) | VAF 25/115 reads (22%) | called by mutect2, pindel, varscan2
- AFM | c.423C>A p.T141= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV99888924; called by muse, mutect2
- ATP2B1 | c.2997A>T p.V999= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV53805919; called by muse, mutect2, varscan2
- CHRM4 | c.495G>A p.A165= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs200635481; called by muse, mutect2, varscan2
- CTTNBP2 | c.2940A>G p.E980= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV50393459; called by muse, mutect2, varscan2
- DHX34 | c.624G>A p.A208= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs375500888; called by muse, mutect2, varscan2
- DNAH11 | c.2367G>A p.L789= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs779115290, COSV60948803; called by muse, mutect2, varscan2
- DNAJC22 | c.714G>A p.L238= | Silent (SNP) | VAF 37/208 reads (18%) | catalogued as COSV67711616; called by muse, mutect2, varscan2
- DSCAML1 | c.2718C>T p.D906= (on ENST00000321322; = p.D846= on NM_020693.4) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1211259899, COSV100356329; called by mutect2, varscan2
- EIF2AK2 | c.708A>G p.Q236= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV51795563; called by muse, mutect2, varscan2
- FAM193A | c.222G>C p.L74= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV61192590; called by muse, mutect2, varscan2
- GRIN2B | c.3339G>A p.P1113= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs200660626; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEY1 | c.570C>T p.I190= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV61232585; called by muse, mutect2, varscan2
- ITGA1 | c.1584G>A p.V528= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV50878895; called by muse, mutect2, varscan2
- KMT2B | c.4515C>T p.F1505= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs993468868; called by muse, mutect2
- LRP2BP | c.27C>G p.P9= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV60749611; called by muse, mutect2, varscan2
- MMP21 | c.786C>T p.D262= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs146537734; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRXN1 | c.1326A>T p.V442= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV100455612; called by muse, mutect2, varscan2
- PGLS | c.729G>A p.A243= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs779076948, COSV53114214; called by muse, mutect2
- PHF12 | c.2268G>A p.Q756= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV52018686; called by muse, mutect2, varscan2
- PSENEN | c.117A>T p.R39= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV53074242; called by muse, mutect2, varscan2
- PTPRT | c.1128C>T p.P376= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1315809674, COSV61963478; called by muse, mutect2
- RAB1B | c.96G>A p.T32= | Silent (SNP) | VAF 34/297 reads (11%) | catalogued as rs748997758, COSV57582068; called by muse, mutect2, varscan2
- RABIF | c.168C>T p.D56= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs186655403; called by muse, mutect2, varscan2
- SFTPA2 | c.333C>G p.L111= | Silent (SNP) | VAF 20/390 reads (5%) | catalogued as COSV64882349; called by muse, mutect2
- SLC13A5 | c.258C>A p.T86= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53422389; called by muse, mutect2, varscan2
- SLC24A4 | c.1314C>T p.C438= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs765282621, COSV54110065; called by muse, mutect2, varscan2
- SLC5A4 | c.672C>T p.N224= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs752335889, COSV56669426; called by muse, mutect2
- SLC6A18 | c.786C>T p.F262= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV57249603; called by muse, mutect2, varscan2
- TRIM17 | c.627G>A p.T209= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs543903675, COSV52857010; called by muse, mutect2
- VCAN | c.2292A>G p.R764= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV54101768; called by muse, mutect2, varscan2
- ZNF600 | c.309C>T p.I103= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as COSV57742064; called by muse, mutect2, varscan2
- RAPH1 | c.733-8329T>C | Intron (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100051625; called by muse, mutect2, varscan2
